CCDI case PBCIMN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/9b39ec8b-9cd7-4005-a7ce-1e947b9aba93

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 10.2 years (3,736 days).

Biospecimens (3 samples)
- Samples 0DT1ZW, 0DT20V (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT20J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
